FM case AD6426 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/cd7e514f-71ba-4cc1-b74a-a22c6248169c

Female, 53.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
